Somatic mutation profile of tumor specimen TCGA-CN-6016-01A (aliquot TCGA-CN-6016-01A-11D-1683-08) from TCGA case TCGA-CN-6016, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.8 years (23,664 days).
Specimen TCGA-CN-6016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e931e873-6eeb-41ea-b990-e80dbf758ce4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6016-10A (Blood Derived Normal), aliquot TCGA-CN-6016-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a127251-2d0e-4f50-b2e7-71da2937d008

The open-access MAF lists 125 somatic variants for this specimen: 88 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 34, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, 3'Flank 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS4 | c.514T>C p.S172P | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs756741155, COSV100917447; called by muse, mutect2, varscan2
- ARHGAP1 | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100357914; called by mutect2, varscan2
- ARID4B | c.2657G>C p.R886T | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.027); catalogued as COSV99935595; called by muse, mutect2, varscan2
- ASNS | c.142C>G p.H48D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99445854, COSV99445917; called by muse, varscan2
- BRK1 | c.94A>G p.I32V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.678); catalogued as COSV99845206; called by muse, mutect2
- C1GALT1C1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100485613; called by muse, mutect2, varscan2
- CCDC61 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376150047; called by muse, mutect2
- CD160 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99353438; called by muse, varscan2
- CLEC4E | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100222629; called by muse, mutect2, varscan2
- CNKSR3 | c.50G>C p.R17T | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV101659530; called by muse, mutect2, varscan2
- DEPDC1 | c.1869G>A p.M623I (on ENST00000456315 / NM_001114120.3; = p.M339I on NM_017779.6) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100920304; called by muse, mutect2
- DHX16 | c.2063A>T p.Y688F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.788); catalogued as COSV99527934; called by muse, mutect2, varscan2
- DMD | c.1565G>C p.G522A | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV99922228; called by muse, mutect2, varscan2
- DYNC1H1 | c.1666A>T p.R556W | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100794851; called by muse, mutect2, varscan2
- DYSF | c.3863C>T p.P1288L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as CD1414232, COSV99246897; called by muse, mutect2, varscan2
- EPB41L5 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs1293517357, COSV99758649; called by muse, mutect2, varscan2
- EXOSC4 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV100284052; called by muse, mutect2
- FAM110B | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100826126, COSV64068214; called by muse, mutect2, varscan2
- FAM13A | c.2529G>C p.Q843H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99983613; called by muse, mutect2, varscan2
- FAM184A | c.2848A>G p.I950V | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.054); catalogued as rs762315481, COSV100137771; called by muse, mutect2, varscan2
- GIGYF2 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV101004322; called by muse, mutect2
- GPATCH1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as rs1235236536, COSV99404006; called by muse, mutect2, varscan2
- GRK5 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.34); catalogued as COSV100963052; called by muse, mutect2, varscan2
- GZMK | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.534); catalogued as COSV99140887; called by muse, mutect2, varscan2
- HEATR1 | c.4847G>A p.R1616H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749879063, COSV63982876; called by muse, mutect2, varscan2
- HECTD4 | c.11605G>A p.V3869I | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs749128238, COSV101107460; called by muse, mutect2, varscan2
- HECTD4 | c.6656G>A p.R2219K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101107462; called by muse, mutect2
- IGLV4-69 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as rs376120930; called by muse, mutect2, varscan2
- IL17RC | c.619C>T p.R207C (on ENST00000295981 / NM_153461.4; = p.R136C on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs747284516, COSV99924619; called by muse, mutect2, varscan2
- KIAA1549L | c.3967G>C p.E1323Q (on ENST00000321505; = p.E1620Q on NM_012194.3) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV99683455; called by muse, mutect2
- KLB | c.2793C>G p.F931L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV99962140; called by muse, mutect2, varscan2
- KLHDC3 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55064097; called by muse, mutect2, varscan2
- KLHL24 | c.298A>G p.R100G | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV99664915; called by muse, mutect2, varscan2
- KLHL42 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 50/429 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779004279, COSV101179762, COSV67145834; called by muse, mutect2, varscan2
- LAMB4 | c.3670G>T p.V1224L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99223942; called by muse, mutect2, varscan2
- LAMB4 | c.3424C>T p.P1142S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs866522788, COSV99223944; called by muse, mutect2, varscan2
- MADD | c.1876A>G p.M626V | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs191553785, COSV100211432; called by muse, mutect2, varscan2
- MRPL9 | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs746064320, COSV100162527; called by muse, mutect2, varscan2
- MYH9 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV53391823; called by muse, mutect2
- NCAPH | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV99545819; called by muse, mutect2, varscan2
- NEB | c.9611T>C p.M3204T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV99422287; called by muse, mutect2, varscan2
- NID2 | c.898T>C p.F300L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV99356501; called by mutect2, varscan2
- NIN | c.6124G>A p.E2042K (on ENST00000382041 / NM_182946.1; = p.E1329K on NM_016350.4) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99813468; called by muse, mutect2
- NOTCH1 | c.3664G>A p.V1222M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs112900950, COSV53084637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOX4 | c.112A>G p.N38D | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99630471; called by muse, mutect2, varscan2
- NUPR1 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.759); catalogued as COSV61405021; called by muse, mutect2, varscan2
- OR3A1 | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV60162547, COSV60163767; called by muse, mutect2, varscan2
- OSBPL6 | c.2084G>A p.R695K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.58); catalogued as rs1425132741, COSV99507390; called by muse, mutect2
- PAPPA2 | c.4365G>C p.Q1455H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV100868085; called by muse, mutect2, varscan2
- PCDH18 | c.2297A>G p.N766S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV100787289; called by muse, mutect2, varscan2
- PCDHB1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV60629956; called by muse, mutect2
- PDZD8 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as rs150304837; called by muse, mutect2, varscan2
- PICK1 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV63661831; called by muse, mutect2, varscan2
- PLXNA2 | c.5080G>A p.D1694N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs760643170, COSV100885445; called by muse, mutect2, varscan2
- PRDM5 | c.886A>G p.I296V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99310529; called by muse, mutect2
- PRMT5 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs766424540, COSV99362978; called by mutect2, varscan2
- RAB34 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 32/142 reads (23%) | catalogued as COSV56387148; called by muse, mutect2, varscan2
- RCOR2 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100036184; called by muse, mutect2, varscan2
- RHEX | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.377); catalogued as rs781803585, COSV58980187; called by muse, mutect2, varscan2
- RNF214 | c.572A>T p.D191V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100326677, COSV56120136; called by muse, mutect2, varscan2
- RPS6KA2 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs756715388, COSV55820091; called by muse, mutect2, varscan2
- RTP1 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as COSV56618441; called by muse, mutect2, varscan2
- SALL1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99173785; called by muse, mutect2, varscan2
- SI | c.1838A>T p.E613V | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); catalogued as COSV100015463; called by muse, mutect2, varscan2
- SLC12A8 | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV100102327; called by muse, mutect2, varscan2
- SNRPA1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.156); catalogued as COSV54258375, COSV99574565; called by muse, mutect2, varscan2
- SOAT2 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100037462; called by muse, mutect2, varscan2
- SPESP1 | c.1018T>C p.S340P | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV99533823; called by mutect2, varscan2
- SURF2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs1182952634, COSV64332277, COSV64332613; called by muse, mutect2
- TACR2 | c.938+2T>C p.X313_splice | Splice Site (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100964804; called by muse, mutect2, varscan2
- TMED5 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.837); catalogued as COSV100939161, COSV64756953; called by muse, mutect2, varscan2
- TRAK1 | c.1267A>G p.M423V (on ENST00000327628 / NM_001349247.2; = p.M365V on NM_014965.5) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as COSV100409984; called by muse, varscan2
- TRPV3 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767538050, COSV100027704, COSV100028221; called by muse, mutect2, varscan2
- TTN | c.4714C>T p.R1572* (on ENST00000591111; = p.R1526* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as rs1554008881, COSV60315148; ClinVar: uncertain significance; called by muse, mutect2
- TUT7 | c.3378+1G>A p.X1126_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99462981; called by muse, mutect2
- UNG | c.175G>C p.G59R (on ENST00000242576 / NM_080911.3; = p.G50R on NM_003362.4) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99655341; called by muse, mutect2
- USP15 | c.2158G>C p.G720R (on ENST00000280377 / NM_001351159.2; = p.G691R on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99739498; called by muse, mutect2, varscan2
- UVRAG | c.1310G>A p.R437K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100638356; called by muse, mutect2, varscan2
- VEPH1 | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.505); catalogued as COSV100747545; called by muse, mutect2, varscan2
- XRN2 | c.2009C>T p.T670I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101018318; called by muse, mutect2
- ZNF211 | c.160C>G p.Q54E (on ENST00000347302 / NM_198855.4; = p.Q67E on NM_006385.5) | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99560267; called by muse, mutect2, varscan2
- ZNF491 | c.607C>G p.R203G | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV100021891, COSV60058913; called by muse, mutect2, varscan2
- ZNF766 | c.71A>T p.K24I | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100765345; called by muse, mutect2, varscan2
- FAT1 | c.4026dup p.I1343Yfs*2 | Frame Shift Ins (INS) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- FCGBP | c.2869G>C p.D957H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KIR3DL1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); called by muse, varscan2
- MBD6 | c.1273del p.H425Tfs*62 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | called by mutect2, pindel, varscan2
- CATSPER4 | c.1101G>A p.S367= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs1407622833, COSV100128370; called by muse, mutect2, varscan2
- CHST6 | c.144G>A p.S48= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1435060387, COSV59999392; called by muse, mutect2
- CKAP5 | c.5559A>G p.L1853= (on ENST00000529230 / NM_001008938.4; = p.L1793= on NM_014756.3) | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100370764; called by muse, mutect2, varscan2
- CNOT3 | c.1494G>C p.V498= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99651829; called by muse, mutect2, varscan2
- COL19A1 | c.546C>T p.V182= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100506250; called by muse, mutect2, varscan2
- DCLK1 | c.225C>T p.A75= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs770858785, COSV99711069; called by muse, mutect2, varscan2
- DDX59 | c.801C>T p.F267= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs760576400, COSV100494459; called by muse, mutect2, varscan2
- DSEL | c.2133A>G p.G711= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100025623; called by muse, mutect2, varscan2
- F7 | c.1254G>A p.L418= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100661011, COSV60646165; called by muse, mutect2, varscan2
- GPR179 | c.6294C>T p.S2098= (on ENST00000621958; = p.S2097= on NM_001004334.4) | Silent (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- GSTM4 | c.45C>T p.H15= | Silent (SNP) | VAF 25/181 reads (14%) | catalogued as rs368378245; called by muse, mutect2, varscan2
- HAO1 | c.873C>T p.D291= | Silent (SNP) | VAF 19/150 reads (13%) | catalogued as rs770281323, COSV66490893; called by muse, mutect2, varscan2
- HNRNPA3 | c.258T>C p.V86= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV101182913; called by muse, mutect2, varscan2
- ITPR3 | c.1953C>G p.L651= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV65407805; called by muse, mutect2, varscan2
- KCNH6 | c.2458C>T p.L820= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100121009; called by muse, varscan2
- KIF15 | c.2118G>A p.E706= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV100392851; called by muse, mutect2, varscan2
- MCM3 | c.1122A>T p.R374= (on ENST00000229854 / NM_001366374.2; = p.R364= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100008805; called by muse, mutect2, varscan2
- MRC1 | c.3060C>T p.F1020= | Silent (SNP) | VAF 43/230 reads (19%) | called by muse, mutect2, varscan2
- OR1N1 | c.138C>T p.A46= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100509745; called by muse, mutect2
- ORC2 | c.1014C>A p.V338= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV99309536; called by muse, mutect2, varscan2
- POTEF | c.2481C>T p.F827= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV100664882; called by muse, mutect2, varscan2
- RARB | c.522C>T p.C174= (on ENST00000383772 / NM_001290216.2; = p.C167= on NM_000965.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100412419; called by muse, mutect2, varscan2
- RGR | c.543C>G p.L181= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV63893959; called by muse, mutect2
- RIC8A | c.594G>A p.L198= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100254802; called by muse, mutect2, varscan2
- SLC4A4 | c.1299T>C p.C433= (on ENST00000264485 / NM_001098484.3; = p.C389= on NM_003759.4) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99140121; called by muse, mutect2, varscan2
- TASOR2 | c.7230T>C p.D2410= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV100050461; called by muse, mutect2, varscan2
- TDP2 | c.480C>T p.Y160= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100593659; called by muse, mutect2, varscan2
- TDRD10 | c.171C>T p.F57= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100872973, COSV100873088; called by muse, mutect2
- TMEM236 | c.867C>G p.L289= | Silent (SNP) | VAF 53/340 reads (16%) | called by muse, mutect2, varscan2
- TRERF1 | c.2604G>A p.L868= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs143046982; called by muse, mutect2, varscan2
- UNC5C | c.144A>G p.E48= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV71662966; called by muse, mutect2, varscan2
- USH2A | c.11949G>A p.L3983= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as COSV56322570; called by muse, mutect2, varscan2
- XYLT1 | c.2181C>T p.I727= | Silent (SNP) | VAF 32/189 reads (17%) | catalogued as rs112238716; called by muse, mutect2, varscan2
- ZW10 | c.186G>A p.Q62= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV99562662; called by mutect2, varscan2
- AL353804.7 | chrX:73846579 G>C | 5'Flank (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- CRNKL1 | c.-2T>C | 5'UTR (SNP) | VAF 14/97 reads (14%) | catalogued as COSV99844748; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640770 C>T | 3'Flank (SNP) | VAF 4/58 reads (7%) | catalogued as COSV99194822; called by muse, mutect2
